Somatic mutation profile of tumor specimen a176fcc2-97b5-45c3-a0f3-3b2e41 (aliquot a176fcc2-97b5-45c3-a0f3-3b2e41_D6_1) from CPTAC case 11BR042, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 71.4 years (26,067 days).
Specimen a176fcc2-97b5-45c3-a0f3-3b2e41: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e1e1bf0-8ccf-4530-88eb-819788eaaa5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 6e370163-4c31-4b23-be51-8d5c66 (Blood Derived Normal), aliquot 6e370163-4c31-4b23-be51-8d5c66_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71db08fd-95a0-4f21-950f-de062500a01f

The open-access MAF lists 32 somatic variants for this specimen: 22 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 8, 3'Flank 1, In Frame Del 1, Splice Region 1, Frame Shift Del 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP3K9 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as rs1220234795, COSV101173607; called by muse, mutect2
- MTMR3 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 18/243 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100070996; called by muse, mutect2
- NBEAL2 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 24/491 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.024); catalogued as rs746838327; ClinVar: uncertain significance; called by muse, mutect2
- NFKBIL1 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs776864117, COSV101092906; called by muse, mutect2
- PCDHB15 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 52/544 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV99178820; called by muse, mutect2
- PRKACA | c.589T>C p.W197R | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1336753127, COSV58066592, COSV58067279, COSV58070561; called by muse, mutect2, varscan2
- RBPMS2 | c.92G>T p.R31L | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55603568; called by muse, mutect2, varscan2
- SGK3 | c.894A>G p.G298= | Splice Region (SNP) | VAF 9/32 reads (28%) | catalogued as rs1032147306; called by muse, mutect2, varscan2
- SSX7 | c.402C>A p.N134K | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV53340677; called by muse, mutect2, varscan2
- TOPBP1 | c.750G>T p.K250N | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53433026, COSV99605096; called by muse, mutect2
- TTN | c.18239C>T p.T6080M (on ENST00000591111; = p.T5153M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/202 reads (9%) | PolyPhen probably damaging (0.988); catalogued as rs199564845; ClinVar: uncertain significance; called by muse, mutect2
- TUBAL3 | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 129/379 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as rs988254391; called by muse, mutect2, varscan2
- ANO1 | c.1870del p.Y624Tfs*34 | Frame Shift Del (DEL) | VAF 35/145 reads (24%) | called by mutect2, pindel, varscan2
- DDX3X | c.680C>T p.S227F (on ENST00000399959; = p.S228F on NM_001356.5) | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK5 | c.926A>C p.K309T | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- MS4A4E | c.97A>G p.K33E | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- OPCML | c.790G>T p.A264S | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PIK3CA | c.322_333del p.R108_K111del | In Frame Del (DEL) | VAF 15/49 reads (31%) | called by mutect2, pindel
- PRAMEF15 | c.429G>A p.M143I | Missense Mutation (SNP) | VAF 68/614 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- SH3BP2 | c.1448G>A p.G483E | Missense Mutation (SNP) | VAF 114/447 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UGT2B11 | c.335A>C p.E112A | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2
- ZSCAN22 | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 108/438 reads (25%) | called by muse, varscan2
- ACTR10 | c.681A>G p.Q227= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as rs752882776; called by muse, mutect2, varscan2
- CFAP20DC | c.1032T>A p.I344= (on ENST00000482387 / NM_001351530.2; = p.I219= on NM_198463.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- CFAP61 | c.2004C>T p.I668= | Silent (SNP) | VAF 41/125 reads (33%) | catalogued as COSV99845274; called by muse, mutect2, varscan2
- CNTNAP5 | c.2448C>T p.S816= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as COSV70507331; called by muse, mutect2, varscan2
- DAPK3 | c.1203C>T p.G401= | Silent (SNP) | VAF 22/334 reads (7%) | catalogued as rs767578366, COSV56662365; called by muse, mutect2
- MED12L | c.861G>A p.S287= | Silent (SNP) | VAF 40/113 reads (35%) | called by muse, mutect2, varscan2
- TMEM201 | c.1638C>A p.P546= | Silent (SNP) | VAF 50/317 reads (16%) | called by muse, mutect2, varscan2
- UBE2QL1 | c.129C>T p.D43= | Silent (SNP) | VAF 43/167 reads (26%) | called by muse, mutect2, varscan2
- EPHA10 | chr1:37715890 C>T | 3'Flank (SNP) | VAF 14/133 reads (11%) | called by muse, mutect2, varscan2
- PSG9 | c.1243+145A>G | Intron (SNP) | VAF 26/91 reads (29%) | catalogued as rs758337749; called by mutect2, varscan2
